MMRF case MMRF_1960 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/090f36ef-3fc1-48fb-b4be-6450d7483487

Demographics
Sex at birth: male; Race: asian; Ethnicity: not hispanic or latino; Age at index: 72 years; Vital status: Dead; Days to death: 575 days (1.6 years); Cause of death: Not Cancer Related.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 72.3 years (26,397 days); ISS stage: III; Days to last known disease status: 575 days (1.6 years); Days to last follow up: 575 days (1.6 years).
   Treatment given: Therapeutic agents: Bortezomib + Prednisone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 315 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 35 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 36 days; Days to treatment end: 315 days.
   Treatment given: Therapeutic agents: Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 525 days (1.4 years); Days to treatment end: 565 days (1.5 years).

Follow-up (1 entry)
- Follow-up contact recording only the day: day 575.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 0 (ECOG 1): M Protein 7.33 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.77 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 570 mg/dL; Immunoglobulin G 80.6 g/L; Immunoglobulin A 0.3 g/L; Immunoglobulin M 0.23 g/L; Beta 2 Microglobulin 17.7 µg/mL; Lactate Dehydrogenase 4.6 µkat/L; Hemoglobin 5.08 mmol/L; Leukocytes 5.8 ×10⁹/L; Absolute Neutrophil 4.2 ×10⁹/L; Platelets 213 ×10⁹/L; Creatinine 358 µmol/L; Calcium 2.41 mmol/L; Albumin 31 g/L; Total Protein 13.2 g/dL; Glucose 6.2 mmol/L; C-Reactive Protein 0.8 mg/dL.
- Day 105 (ECOG 2): M Protein 4.53 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.54 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 166 mg/dL; Immunoglobulin G 56.4 g/L; Immunoglobulin A 0.3 g/L; Immunoglobulin M 0.18 g/L; Hemoglobin 6.14 mmol/L; Leukocytes 2.4 ×10⁹/L; Absolute Neutrophil 1 ×10⁹/L; Platelets 101 ×10⁹/L; Creatinine 256 µmol/L; Calcium 2.34 mmol/L; Albumin 34 g/L; Total Protein 10.5 g/dL; Glucose 6.2 mmol/L.
- Day 175 (ECOG 2): M Protein 3.6 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.86 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 105 mg/dL; Immunoglobulin G 49.4 g/L; Immunoglobulin A 0.3 g/L; Hemoglobin 5.52 mmol/L; Leukocytes 2.7 ×10⁹/L; Absolute Neutrophil 1.5 ×10⁹/L; Platelets 56 ×10⁹/L; Creatinine 267 µmol/L; Calcium 2.4 mmol/L; Albumin 36 g/L; Total Protein 9.6 g/dL; Glucose 6.2 mmol/L.
- Day 280 (ECOG 1): M Protein 3.04 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.51 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 84.8 mg/dL; Immunoglobulin G 38.7 g/L; Immunoglobulin A 0.36 g/L; Immunoglobulin M 0.22 g/L; Hemoglobin 5.02 mmol/L; Leukocytes 3 ×10⁹/L; Absolute Neutrophil 2.7 ×10⁹/L; Platelets 48 ×10⁹/L; Creatinine 212 µmol/L; Calcium 2.2 mmol/L; Albumin 30 g/L; Total Protein 8.9 g/dL; Glucose 10.7 mmol/L.
- Day 343 (ECOG 1): M Protein 3.13 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.59 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 132 mg/dL; Immunoglobulin G 45.7 g/L; Immunoglobulin A 0.3 g/L; Immunoglobulin M 0.2 g/L; Hemoglobin 7.13 mmol/L; Leukocytes 4.1 ×10⁹/L; Absolute Neutrophil 2.1 ×10⁹/L; Platelets 135 ×10⁹/L; Creatinine 236 µmol/L; Calcium 2.34 mmol/L; Albumin 33 g/L; Total Protein 9 g/dL; Glucose 6.6 mmol/L.
- Day 476: M Protein 3.05 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.66 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 96 mg/dL; Immunoglobulin G 32.1 g/L; Immunoglobulin A 0.27 g/L; Immunoglobulin M 0.29 g/L; Lactate Dehydrogenase 4.63 µkat/L; Hemoglobin 6.2 mmol/L; Leukocytes 5.2 ×10⁹/L; Absolute Neutrophil 2.9 ×10⁹/L; Platelets 191 ×10⁹/L; Creatinine 233 µmol/L; Calcium 2.28 mmol/L; Albumin 29 g/L; Total Protein 8.3 g/dL; Glucose 7 mmol/L.
- Day 525 (ECOG 2): M Protein 2.88 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.58 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 117 mg/dL; Immunoglobulin G 30.5 g/L; Immunoglobulin A 0.34 g/L; Immunoglobulin M 0.26 g/L; Hemoglobin 6.7 mmol/L; Leukocytes 8.1 ×10⁹/L; Absolute Neutrophil 6.2 ×10⁹/L; Platelets 195 ×10⁹/L; Creatinine 277 µmol/L; Calcium 2.24 mmol/L; Albumin 25 g/L; Glucose 10.3 mmol/L.

Other clinical attributes
- Day 0: Weight: 54 kg; Height: 164 cm.

Family history
- Relative with cancer history: yes; Relationship type: Mother; Relationship sex at birth: female.

Biospecimens (2 samples)
- Sample MMRF_1960_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 0 days.
- Sample MMRF_1960_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 0 days.
